Somatic mutation profile of tumor specimen MP2PRT-PAUAXY-TMP1-B (aliquot MP2PRT-PAUAXY-TMP1-B-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUAXY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,712 days).
Specimen MP2PRT-PAUAXY-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd76a4ab-d236-4dbd-880a-d2762f3f90d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUAXY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUAXY-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ff6c88e-3397-460f-ad54-e99fec6a46d2

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Nonsense Mutation 2, Intron 2, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDA | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs132630313, CM001981, CM105061, CM980585, COSV65776984; ClinVar: pathogenic; called by muse, mutect2
- MTOR | c.5930C>A p.T1977K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: not provided; called by mutect2, varscan2
- CEP164 | c.3866C>T p.S1289L | Missense Mutation (SNP) | VAF 81/690 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs758693012; called by muse, mutect2, varscan2
- DDR2 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 90/291 reads (31%) | catalogued as rs1056323839, COSV63370359; called by muse, mutect2, varscan2
- GTSE1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as rs751933283; called by muse, mutect2, varscan2
- MAGEE2 | c.836G>T p.W279L | Missense Mutation (SNP) | VAF 410/505 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV64897829; called by muse, mutect2, varscan2
- MTOR | c.6050T>C p.I2017T | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63878340, COSV63880423; called by muse, mutect2, varscan2
- SH3RF3 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 64/460 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs1164038816, COSV100513788; called by muse, mutect2, varscan2
- VWA5A | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs372417602, COSV64413621; called by muse, mutect2, varscan2
- CEBPZOS | c.87T>G p.F29L | Missense Mutation (SNP) | VAF 165/419 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DOCK6 | c.5332A>G p.K1778E | Missense Mutation (SNP) | VAF 175/394 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TBX21 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 97/257 reads (38%) | called by muse, mutect2, varscan2
- UBR5 | c.891_893del p.L299del | In Frame Del (DEL) | VAF 75/188 reads (40%) | called by mutect2, pindel, varscan2
- KCNQ3 | c.2502C>T p.A834= | Silent (SNP) | VAF 121/510 reads (24%) | catalogued as rs1248992112, COSV101196100, COSV66478182; called by muse, mutect2, varscan2
- CYBA | c.369+905G>A | Intron (SNP) | VAF 143/343 reads (42%) | called by muse, varscan2
- MAP3K7CL | c.371-15782C>T | Intron (SNP) | VAF 117/326 reads (36%) | catalogued as rs1015567004; called by muse, mutect2, varscan2
